Gene-level copy-number profile of tumor specimen TCGA-IQ-A61J-01A from TCGA case TCGA-IQ-A61J, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 54.5 years (19,913 days).
Specimen TCGA-IQ-A61J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.00392cb3-cb0f-433d-a934-bbecf372c99b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IQ-A61J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/134fdb16-e31f-44d2-8df1-cdcbc5cc7861

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 2: 11,052; copy number 3: 3,856; copy number 4: 36,918; copy number 5: 4,506; copy number 6: 2,235; copy number 7: 715; copy number 8: 336; copy number 9: 60; copy number 10: 17; copy number 11: 12; copy number 13: 23; copy number 15: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IQ-A61J-01A-11D-A30D-01): tumor purity 0.41, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:78,597,239–87,158,363, 48 genes (within-gene range 0–2): ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 143 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:63,759,892–64,811,294, 60 genes, copy number 9: C11orf95, RN7SL596P, SPINDOC, ATP5MGP1, MARK2, RNU6-1306P, RCOR2, NAA40, RNU6-45P, COX8A, AP000721.1, OTUB1, MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1, STIP1, FERMT3, TRPT1, NUDT22, AP001453.1, DNAJC4, VEGFB, FKBP2, AP001453.3, PPP1R14B, PPP1R14B-AS1, AP001453.2, PLCB3, BAD, GPR137, KCNK4, KCNK4-TEX40, Y_RNA, CATSPERZ, ESRRA, TRMT112, PRDX5, AP003774.2, CCDC88B, MIR7155, RPS6KA4, MIR1237, LINC02723, AP003774.1, LINC02724, AP005273.2, AP005273.1, AP006288.1, SLC22A11, SLC22A12, NRXN2, NRXN2-AS1, RASGRP2, PYGM, SF1, AP001462.1, MAP4K2, MEN1.
- chr11:81,821,272–82,718,299, 1 gene, copy number 15 (within-gene range 6–15): MIR4300HG.
- chr11:81,890,741–85,627,922, 47 genes, copy number 10–15 (within-gene range 2–15): MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2, DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1.
- chr11:98,938,912–102,530,750, 35 genes, copy number 11–13: AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
